Somatic mutation profile of tumor specimen TCGA-BA-6870-01A (aliquot TCGA-BA-6870-01A-11D-1870-08) from TCGA case TCGA-BA-6870, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; Tumor grade: G2; Age at diagnosis: 60.8 years (22,222 days).
Specimen TCGA-BA-6870-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c263a3b8-8f41-49fc-a756-327069d3fe8a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BA-6870-10A (Blood Derived Normal), aliquot TCGA-BA-6870-10A-01D-1870-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5fdd6ddd-3c51-405a-b0fd-0ffd6456457b

The open-access MAF lists 100 somatic variants for this specimen: 78 protein-altering or splice-affecting, 21 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, Silent 21, Frame Shift Ins 4, Nonsense Mutation 4, Frame Shift Del 3, In Frame Del 2, Splice Site 2, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.725G>A p.C242Y | Missense Mutation (SNP) | VAF 39/108 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912655, CM910618, COSV52661189, COSV52677418, COSV52689710; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCD4 | c.274C>G p.L92V | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as COSV100084622, COSV53993802; called by muse, mutect2, varscan2
- ADAM15 | c.2366A>G p.D789G (on ENST00000356955 / NM_207197.3; = p.D764G on NM_207195.3) | Missense Mutation (SNP) | VAF 18/201 reads (9%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); catalogued as COSV99665448; called by muse, mutect2
- AKR1B10 | c.469C>A p.L157I | Missense Mutation (SNP) | VAF 39/201 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV100610273; called by muse, mutect2, varscan2
- ANKRD13C | c.1195A>C p.I399L | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV99257899; called by muse, mutect2, varscan2
- BRCA2 | c.7873A>T p.R2625* | Nonsense Mutation (SNP) | VAF 28/105 reads (27%) | catalogued as COSV101204703; called by muse, mutect2, varscan2
- CASQ2 | c.446T>G p.I149S | Missense Mutation (SNP) | VAF 50/186 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1060502165, COSV54775141; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC88A | c.947G>A p.R316Q | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs754636259, COSV55058534; called by muse, mutect2, varscan2
- CDH6 | c.910G>C p.E304Q | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as COSV99421170; called by muse, mutect2
- CDH9 | c.307A>G p.I103V | Missense Mutation (SNP) | VAF 100/263 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs1008404444, COSV99162730; called by muse, mutect2, varscan2
- CFH | c.1117C>T p.H373Y | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as rs754477357, COSV100661688; called by muse, mutect2
- CHST8 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52856992; called by muse, mutect2
- CMYA5 | c.7999C>G p.P2667A | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV101484004, COSV101484449; called by muse, mutect2, varscan2
- CNTNAP2 | c.1323G>T p.K441N | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.296); catalogued as COSV100673818, COSV62222914, COSV62267893; called by muse, mutect2, varscan2
- CTTNBP2 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 46/357 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV50390591, COSV50417449; called by muse, mutect2, varscan2
- DIAPH2 | c.1903G>T p.E635* | Nonsense Mutation (SNP) | VAF 22/154 reads (14%) | catalogued as COSV100235187, COSV100235956; called by muse, mutect2, varscan2
- DNAAF1 | c.1385A>G p.Q462R | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs754914584, COSV57577979, COSV57579028; called by muse, varscan2
- DNAH3 | c.6916G>A p.E2306K | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99771260; called by muse, mutect2, varscan2
- DOP1B | c.5105G>A p.R1702H | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs779189283, COSV67693011; called by muse, mutect2, varscan2
- DPY19L2 | c.667G>A p.V223I | Missense Mutation (SNP) | VAF 22/188 reads (12%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.735); catalogued as rs1019297343, COSV100117021; called by muse, mutect2, varscan2
- EEF1A1 | c.86A>G p.Y29C | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV58550426; called by muse, mutect2, varscan2
- EMC2 | c.139A>G p.K47E | Missense Mutation (SNP) | VAF 28/223 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs1032588617, COSV99624654; called by muse, mutect2, varscan2
- ERMAP | c.649A>T p.S217C | Missense Mutation (SNP) | VAF 50/190 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.41); catalogued as COSV100072441; called by muse, mutect2, varscan2
- FASTKD3 | c.1885-2A>G p.X629_splice | Splice Site (SNP) | VAF 20/80 reads (25%) | catalogued as COSV99242726; called by muse, mutect2
- FGD1 | c.946G>T p.A316S | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV100911281, COSV64309488; called by muse, mutect2, varscan2
- GHR | c.1187A>G p.E396G | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs774163051, COSV100052310; called by muse, mutect2, varscan2
- GTF3C1 | c.4397A>G p.K1466R | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.011); catalogued as rs1011800943, COSV100649801; called by muse, mutect2, varscan2
- HADHA | c.1912A>G p.I638V | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs545660610, COSV101024271; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IL1RAPL2 | c.724C>A p.P242T | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.3); catalogued as COSV100782193; called by muse, mutect2, varscan2
- IL1RAPL2 | c.725C>A p.P242Q | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.726); catalogued as COSV100782194; called by muse, mutect2, varscan2
- KMT2D | c.7009C>T p.Q2337* | Nonsense Mutation (SNP) | VAF 18/57 reads (32%) | catalogued as COSV56423351, COSV99986539; called by muse, mutect2, varscan2
- LMTK3 | c.4372G>T p.V1458L | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.872); catalogued as COSV99541335; called by muse, mutect2, varscan2
- LRIG3 | c.3312A>C p.L1104F | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as COSV100292898; called by muse, mutect2, varscan2
- LRP1B | c.6665A>G p.K2222R | Missense Mutation (SNP) | VAF 40/203 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs945435111, COSV101262134; called by muse, mutect2, varscan2
- LTK | c.1987G>A p.G663R | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs757138946, COSV99541220; called by muse, mutect2, varscan2
- MED23 | c.1558A>G p.I520V | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1372702202, COSV100645468; called by muse, mutect2, varscan2
- MERTK | c.1001T>C p.I334T | Missense Mutation (SNP) | VAF 63/246 reads (26%) | SIFT tolerated (0.72); PolyPhen benign (0.005); catalogued as COSV99775457; called by muse, mutect2, varscan2
- MKNK2 | c.799G>C p.E267Q | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.978); catalogued as COSV99170464; called by muse, mutect2
- MMP8 | c.1084C>T p.P362S | Missense Mutation (SNP) | VAF 12/229 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs996002865, COSV52633680; called by muse, mutect2
- MS4A12 | c.83C>A p.P28H | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.888); catalogued as COSV99189962; called by muse, mutect2, varscan2
- MTBP | c.704C>T p.S235L | Missense Mutation (SNP) | VAF 27/349 reads (8%) | SIFT tolerated (0.73); PolyPhen benign (0.025); catalogued as COSV100011950, COSV100012652, COSV59966168; called by muse, mutect2
- MTREX | c.1679A>G p.N560S | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as COSV100044655; called by muse, mutect2, varscan2
- NCK1 | c.815C>T p.S272L | Missense Mutation (SNP) | VAF 29/205 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV99999898; called by muse, mutect2, varscan2
- NDST4 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV52121427; called by muse, mutect2, varscan2
- NRXN3 | c.1863G>C p.K621N (on ENST00000335750 / NM_001330195.2; = p.K248N on NM_004796.6) | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as COSV100210496; called by muse, mutect2, varscan2
- OGFRL1 | c.377A>G p.N126S | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.489); catalogued as COSV100965816; called by muse, mutect2, varscan2
- OR5I1 | c.844A>G p.I282V | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.13); catalogued as rs781338753, COSV100041753; called by muse, mutect2, varscan2
- PACRGL | c.59A>G p.Y20C | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs760675026, COSV54843118; called by muse, mutect2, varscan2
- PDE9A | c.498-1G>A p.X166_splice | Splice Site (SNP) | VAF 13/53 reads (25%) | catalogued as COSV52326672; called by muse, mutect2
- PDZRN4 | c.2029G>A p.E677K (on ENST00000402685 / NM_001164595.2; = p.E419K on NM_013377.4) | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100115769; called by muse, mutect2, varscan2
- PTPRT | c.1300C>T p.Q434* | Nonsense Mutation (SNP) | VAF 53/119 reads (45%) | catalogued as COSV100631240; called by muse, mutect2, varscan2
- RC3H2 | c.2488G>A p.E830K | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.052); catalogued as COSV100606168; called by muse, mutect2
- SBDS | c.627A>G p.V209= | Splice Region (SNP) | VAF 12/63 reads (19%) | catalogued as rs769195730, COSV99886243; called by muse, mutect2, varscan2
- STAG2 | c.2224C>A p.L742I | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99495731; called by muse, mutect2, varscan2
- SUN5 | c.297G>C p.Q99H | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV100644936; called by muse, mutect2, varscan2
- TBC1D9 | c.1162A>G p.R388G | Missense Mutation (SNP) | VAF 53/183 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV101464418; called by muse, mutect2, varscan2
- THSD4 | c.1612C>T p.P538S | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.343); catalogued as rs773756802, COSV55985133; called by muse, mutect2, varscan2
- TLE6 | c.596G>A p.G199E (on ENST00000246112 / NM_001143986.2; = p.G76E on NM_024760.3) | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.069); catalogued as COSV99858646; called by muse, mutect2
- TRAPPC11 | c.691G>A p.A231T | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV100592079; called by muse, varscan2
- TREML2 | c.177G>T p.R59S | Missense Mutation (SNP) | VAF 52/213 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV101530197, COSV72439070; called by muse, mutect2, varscan2
- TTF1 | c.1282A>G p.M428V | Missense Mutation (SNP) | VAF 74/156 reads (47%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100524900; called by muse, mutect2, varscan2
- WASF3 | c.937C>T p.P313S | Missense Mutation (SNP) | VAF 35/148 reads (24%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV100099732; called by muse, mutect2, varscan2
- XRN2 | c.862G>A p.D288N | Missense Mutation (SNP) | VAF 17/161 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.021); catalogued as COSV101018733; called by muse, mutect2, varscan2
- XRN2 | c.863A>T p.D288V | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.298); catalogued as COSV101018735; called by mutect2, varscan2
- ZMYM6 | c.3560T>G p.I1187S | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.601); catalogued as COSV100593382; called by muse, mutect2, varscan2
- ZNF423 | c.2390C>A p.T797N (on ENST00000563137 / NM_001379286.1; = p.T789N on NM_015069.4) | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.218); catalogued as rs767082011, COSV99284220; called by muse, mutect2, varscan2
- ZNF687 | c.1057C>T p.P353S | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as COSV99650316; called by muse, mutect2, varscan2
- BAG6 | c.1928dup p.M643Ifs*3 (on ENST00000676571; = p.M596Ifs*3 on NM_080702.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 10/30 reads (33%) | called by mutect2, pindel, varscan2
- CYP4A22 | c.728_739del p.Y243_T246del | In Frame Del (DEL) | VAF 15/156 reads (10%) | called by mutect2, pindel
- GALNT10 | c.183_209del p.T62_K70del | In Frame Del (DEL) | VAF 14/132 reads (11%) | called by mutect2, pindel
- GNB2 | c.901_904del p.K301Afs*14 | Frame Shift Del (DEL) | VAF 17/79 reads (22%) | called by mutect2, pindel, varscan2
- MAP2K4 | c.698_711del p.S233* | Frame Shift Del (DEL) | VAF 13/68 reads (19%) | called by mutect2, pindel, varscan2
- NOTCH2 | c.1967del p.H656Lfs*46 | Frame Shift Del (DEL) | VAF 13/83 reads (16%) | called by mutect2, pindel, varscan2
- OR56A1 | c.579dup p.N194* | Frame Shift Ins (INS) | VAF 11/114 reads (10%) | called by mutect2, pindel, varscan2
- PAXIP1 | c.3130dup p.I1044Nfs*21 | Frame Shift Ins (INS) | VAF 23/103 reads (22%) | called by mutect2, pindel, varscan2
- RUNX1T1 | c.589C>G p.L197V (on ENST00000265814 / NM_001198628.1; = p.L170V on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2
- ZNF219 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.217); called by muse, mutect2
- ZNF433 | c.1236dup p.E413* | Frame Shift Ins (INS) | VAF 34/130 reads (26%) | called by mutect2, pindel, varscan2
- BCAN | c.825G>A p.A275= | Silent (SNP) | VAF 25/168 reads (15%) | catalogued as rs776798315, COSV61255405; called by muse, mutect2, varscan2
- CHAF1A | c.981A>G p.K327= | Silent (SNP) | VAF 10/132 reads (8%) | catalogued as COSV100011555; called by muse, mutect2
- DMRT2 | c.1656T>C p.P552= | Silent (SNP) | VAF 22/84 reads (26%) | catalogued as COSV52402119; called by muse, mutect2, varscan2
- DOCK2 | c.5028G>A p.P1676= | Silent (SNP) | VAF 18/181 reads (10%) | catalogued as rs750759661, COSV99916173; called by muse, mutect2, varscan2
- GLUD2 | c.1140C>A p.I380= | Silent (SNP) | VAF 68/312 reads (22%) | catalogued as COSV100047161; called by muse, mutect2, varscan2
- HCFC1 | c.1893T>A p.P631= | Silent (SNP) | VAF 20/98 reads (20%) | catalogued as COSV100130139; called by muse, mutect2, varscan2
- HPR | c.621C>T p.I207= | Silent (SNP) | VAF 19/174 reads (11%) | catalogued as rs1294249105, COSV57181740, COSV99931075; called by muse, mutect2, varscan2
- JAG1 | c.366G>C p.L122= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV99653609; called by muse, varscan2
- NCKAP1L | c.3285G>A p.E1095= | Silent (SNP) | VAF 21/174 reads (12%) | catalogued as COSV99515838; called by muse, mutect2, varscan2
- OR2C3 | c.117G>C p.S39= | Silent (SNP) | VAF 27/147 reads (18%) | catalogued as COSV100825809, COSV63574354, COSV63575018; called by muse, mutect2, varscan2
- PARP11 | c.288C>T p.L96= | Silent (SNP) | VAF 28/214 reads (13%) | catalogued as rs745349560, COSV99958954; called by muse, mutect2, varscan2
- PCDHA5 | c.1515T>C p.S505= | Silent (SNP) | VAF 28/134 reads (21%) | catalogued as COSV100972157; called by muse, varscan2
- PCDHB12 | c.492C>A p.I164= | Silent (SNP) | VAF 11/77 reads (14%) | catalogued as COSV99507986; called by muse, mutect2, varscan2
- PCDHGA6 | c.1749G>A p.E583= | Silent (SNP) | VAF 62/213 reads (29%) | catalogued as COSV99548998; called by muse, mutect2, varscan2
- PRRC2A | c.6402A>G p.E2134= | Silent (SNP) | VAF 30/136 reads (22%) | catalogued as COSV99277789; called by muse, mutect2
- RLF | c.2973A>G p.K991= | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as COSV101035782; called by muse, mutect2, varscan2
- SCO1 | c.846G>A p.R282= | Silent (SNP) | VAF 47/125 reads (38%) | catalogued as COSV99703647; called by muse, mutect2, varscan2
- SPTB | c.5262C>T p.I1754= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as rs142168941, COSV67633441; called by muse, mutect2, varscan2
- THSD4 | c.1611G>A p.V537= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as COSV99967464; called by muse, mutect2, varscan2
- UBFD1 | c.396C>T p.L132= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as rs759699801, COSV99563532; called by muse, mutect2, varscan2
- URB2 | c.3036C>A p.L1012= | Silent (SNP) | VAF 26/75 reads (35%) | catalogued as COSV50984798, COSV99272126; called by muse, mutect2, varscan2
- MIR512-1 | n.80T>A | RNA (SNP) | VAF 28/74 reads (38%) | called by muse, mutect2, varscan2
